Somatic mutation profile of tumor specimen C3L-07671-01 (aliquot CPT0480700006) from CPTAC case C3L-07671, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 50.0 years (18,272 days).
Specimen C3L-07671-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7614cc00-762e-44a7-96c9-87ca9f0982ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07671-31 (Blood Derived Normal), aliquot CPT0480850004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/229557c6-a895-4101-bb7b-58e1aafd819c

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 21, Intron 3, Frame Shift Del 2, Nonsense Mutation 2, Nonstop Mutation 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.4136G>A p.G1379D (on ENST00000614293; = p.G1349D on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/701 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV55800449; called by muse, mutect2
- ACHE | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 99/666 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.42); catalogued as rs566212629; called by muse, mutect2, varscan2
- AFF2 | c.2668C>T p.H890Y | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV54000115; called by muse, mutect2, varscan2
- AMOTL2 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 53/700 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746390676; called by muse, mutect2
- ARHGAP22 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 247/772 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV99985595; called by muse, mutect2, varscan2
- ATG2A | c.2207T>C p.V736A | Missense Mutation (SNP) | VAF 130/358 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs772497802; called by muse, mutect2, varscan2
- ATXN1 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 86/660 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.217); catalogued as rs767419937, COSV99784799, COSV99786246; called by muse, mutect2, varscan2
- C6orf132 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 116/685 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs1391923616, COSV59373164; called by muse, mutect2, varscan2
- CCDC120 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 78/374 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs782463146, COSV64514799; called by muse, mutect2, varscan2
- CDH22 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 48/1054 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746421050; called by muse, mutect2
- CDKL5 | c.2422A>G p.I808V | Missense Mutation (SNP) | VAF 127/218 reads (58%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1395051245; called by muse, mutect2, varscan2
- CELSR2 | c.4486G>A p.G1496R | Missense Mutation (SNP) | VAF 149/403 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1241327662; called by muse, mutect2, varscan2
- CEP250 | c.5956G>A p.E1986K | Missense Mutation (SNP) | VAF 94/1622 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs1361445805; called by muse, mutect2
- DRAXIN | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371982011; called by muse, mutect2, varscan2
- DSP | c.2569G>A p.G857S | Missense Mutation (SNP) | VAF 68/451 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs548695484; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EFTUD2 | c.2194A>G p.I732V | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.268); catalogued as rs772149927; called by muse, mutect2, varscan2
- ELFN1 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 90/694 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs761498559; called by muse, mutect2, varscan2
- FAM149B1 | c.138C>G p.D46E | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV54352826; called by muse, mutect2, varscan2
- GLI3 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 41/417 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs765318570, COSV67884879; called by muse, mutect2, varscan2
- HTR5A | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 158/554 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs200887444; called by muse, varscan2
- KIR2DL4 | c.527G>A p.R176H (on ENST00000396284; = p.R137H on NM_001080770.2) | Missense Mutation (SNP) | VAF 92/686 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs537400112, COSV60877656; called by muse, varscan2
- KLHL20 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 18/568 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1182804972, COSV52940973; called by muse, mutect2
- KMO | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63807701; called by muse, mutect2, varscan2
- LILRB3 | c.1661C>T p.T554M (on ENST00000346401; = p.T542M on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 153/362 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs200874692; called by muse, mutect2, varscan2
- LMX1A | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 41/730 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54219546; called by muse, mutect2
- LRRC37B | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58951798; called by muse, varscan2
- MAST4 | c.4090C>T p.R1364W (on ENST00000403625 / NM_001164664.2; = p.R1175W on NM_015183.3) | Missense Mutation (SNP) | VAF 80/551 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779584143; called by muse, mutect2, varscan2
- MYO18B | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs771830216, COSV59126666; called by muse, mutect2
- NCR2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 63/530 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.08); catalogued as rs574138095, COSV66101090; called by muse, mutect2, varscan2
- NIFK | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 75/385 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs185431138, COSV53534192, COSV99590654; called by muse, mutect2, varscan2
- NPAP1 | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 32/554 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.099); catalogued as COSV61504347; called by muse, mutect2
- PIK3C2B | c.3805C>T p.R1269C | Missense Mutation (SNP) | VAF 40/568 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777242962, COSV65814222; called by muse, mutect2
- RAPGEFL1 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 66/441 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs1387147344, COSV52864624; called by muse, mutect2, varscan2
- RIBC1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.207); catalogued as COSV51448441; called by muse, mutect2, varscan2
- RTL1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 139/515 reads (27%) | catalogued as COSV66016864; called by muse, mutect2, varscan2
- RYR1 | c.3200G>A p.R1067H | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs377381782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEZ6 | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 78/580 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755478298; called by muse, mutect2, varscan2
- SUN2 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 69/369 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs760739182, COSV53301321; called by muse, mutect2, varscan2
- TNFRSF19 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 58/404 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs757269083; called by muse, mutect2, varscan2
- TRPM4 | c.2836G>A p.V946M | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53264019; called by muse, mutect2, varscan2
- UGT3A1 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 68/494 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs772440877, COSV57100205; called by muse, mutect2, varscan2
- ZNF658 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs766015316; called by muse, mutect2, varscan2
- ARID1A | c.1174_1177del p.P392Sfs*40 | Frame Shift Del (DEL) | VAF 125/335 reads (37%) | called by mutect2, pindel, varscan2
- ATP9A | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- CORO6 | c.1037C>G p.P346R | Missense Mutation (SNP) | VAF 125/463 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDX3X | c.162dup p.D55Rfs*8 (on ENST00000399959; = p.D56Rfs*8 on NM_001356.5) | Frame Shift Ins (INS) | VAF 89/210 reads (42%) | called by mutect2, pindel, varscan2
- DMPK | c.356A>G p.E119G | Missense Mutation (SNP) | VAF 63/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.6069C>G p.F2023L | Missense Mutation (SNP) | VAF 97/402 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DPYD | c.1512C>G p.H504Q | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC2H1 | c.8977G>A p.G2993R | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EDAR | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 67/358 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GANC | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 93/255 reads (36%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH15 | c.3646G>T p.E1216* | Nonsense Mutation (SNP) | VAF 74/523 reads (14%) | called by muse, mutect2, varscan2
- NDUFV2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 111/468 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPY | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 124/532 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NUDT7 | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR14K1 | c.943T>A p.*315Rext*? | Nonstop Mutation (SNP) | VAF 42/222 reads (19%) | called by muse, mutect2, varscan2
- OR51E1 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- SLC6A19 | c.172T>A p.F58I | Missense Mutation (SNP) | VAF 53/412 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBX21 | c.1459T>C p.S487P | Missense Mutation (SNP) | VAF 20/638 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- TP53 | c.224_231delinsGGT p.P75Rfs*72 | Frame Shift Del (DEL) | VAF 228/631 reads (36%) | called by pindel, varscan2*
- TPX2 | c.1233A>G p.I411M | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE2V2 | c.45G>T p.L15F | Missense Mutation (SNP) | VAF 116/357 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBFD1 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 40/827 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.207); called by muse, mutect2
- VSTM2B | c.697_720del p.A233_A240del | In Frame Del (DEL) | VAF 176/547 reads (32%) | called by mutect2, pindel, varscan2
- ZBTB6 | c.179A>C p.D60A | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZC3H18 | c.1135T>G p.F379V | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- APLP1 | c.9C>A p.P3= | Silent (SNP) | VAF 64/411 reads (16%) | catalogued as rs1371952562; called by muse, mutect2, varscan2
- CHST5 | c.690G>A p.L230= | Silent (SNP) | VAF 99/586 reads (17%) | catalogued as rs753590914; called by muse, mutect2, varscan2
- EXOSC6 | c.165G>A p.L55= | Silent (SNP) | VAF 18/520 reads (3%) | called by muse, mutect2
- FAM126A | c.378G>A p.T126= | Silent (SNP) | VAF 29/286 reads (10%) | catalogued as rs766096775; called by muse, mutect2, varscan2
- FAT4 | c.7725G>A p.T2575= | Silent (SNP) | VAF 26/438 reads (6%) | called by muse, mutect2
- GLI3 | c.3435C>T p.A1145= | Silent (SNP) | VAF 42/797 reads (5%) | catalogued as rs776456548; called by muse, mutect2
- GLP1R | c.1095C>T p.V365= | Silent (SNP) | VAF 135/453 reads (30%) | called by muse, mutect2, varscan2
- HNRNPL | c.240C>G p.A80= | Silent (SNP) | VAF 82/674 reads (12%) | called by muse, mutect2, varscan2
- IL17RC | c.1236G>C p.L412= (on ENST00000295981 / NM_153461.4; = p.L326= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 60/386 reads (16%) | catalogued as rs375887120; called by muse, mutect2, varscan2
- LPO | c.1377C>A p.V459= | Silent (SNP) | VAF 75/525 reads (14%) | catalogued as COSV51862845; called by muse, mutect2, varscan2
- MUC16 | c.14772T>C p.T4924= | Silent (SNP) | VAF 80/388 reads (21%) | called by muse, mutect2, varscan2
- PCK1 | c.723C>G p.L241= | Silent (SNP) | VAF 140/908 reads (15%) | catalogued as COSV60126572; called by mutect2, varscan2
- RGL3 | c.831G>A p.S277= | Silent (SNP) | VAF 68/498 reads (14%) | catalogued as rs1355802394; called by muse, mutect2, varscan2
- SIPA1 | c.2754G>A p.S918= | Silent (SNP) | VAF 53/410 reads (13%) | catalogued as rs181019059; called by muse, mutect2, varscan2
- SLA | c.282C>T p.A94= (on ENST00000338087 / NM_001045556.3; = p.A134= on NM_006748.4) | Silent (SNP) | VAF 14/490 reads (3%) | catalogued as rs1277867361, COSV55070892; called by muse, mutect2
- SPAG16 | c.102C>T p.D34= | Silent (SNP) | VAF 96/528 reads (18%) | catalogued as rs760771387; called by muse, mutect2, varscan2
- SPEG | c.1740A>T p.T580= | Silent (SNP) | VAF 75/609 reads (12%) | called by muse, mutect2, varscan2
- SYNGR4 | c.567C>T p.T189= | Silent (SNP) | VAF 19/644 reads (3%) | called by muse, mutect2
- VWA5B1 | c.1839C>T p.P613= | Silent (SNP) | VAF 140/363 reads (39%) | catalogued as rs896932886; called by muse, mutect2, varscan2
- ZNF541 | c.1572C>T p.A524= | Silent (SNP) | VAF 175/561 reads (31%) | called by muse, mutect2, varscan2
- ZNF853 | c.1908G>A p.P636= | Silent (SNP) | VAF 98/611 reads (16%) | called by muse, mutect2, varscan2
- DST | c.4297-1716G>C | Intron (SNP) | VAF 15/422 reads (4%) | called by muse, mutect2
- KCTD1 | c.-15-45801C>A | Intron (SNP) | VAF 35/270 reads (13%) | catalogued as rs1397346434; called by muse, mutect2, varscan2
- NPL | c.230+183G>T | Intron (SNP) | VAF 59/567 reads (10%) | called by muse, mutect2, varscan2
